Gene-level copy-number profile of tumor specimen TCGA-2G-AAG2-01A from TCGA case TCGA-2G-AAG2, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Choriocarcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 24.5 years (8,957 days).
Specimen TCGA-2G-AAG2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d635e211-16c7-458b-a384-a3866ad414ae.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAG2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/0a0fe36c-61e1-4fe4-9076-970b72703ce9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 631; copy number 2: 17,081; copy number 3: 20,302; copy number 4: 16,985; copy number 5: 510; copy number 6: 2,665; copy number 7: 23; copy number 8: 420; copy number 9: 280.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:33,808,778–33,810,767, 1 gene: AC136428.3.
- chr16:33,938,337–33,950,420, 3 genes: IGHV3OR16-7, AC140658.4, IGHV3OR16-16.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 723 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:137,657,998–138,793,319, 23 genes, copy number 7: AL356234.2, AL356234.1, LINC02539, Y_RNA, WAKMAR2, TNFAIP3, LINC02528, LINC02865, RPSAP42, PERP, ARFGEF3, PBOV1, SMIM28, AL031003.1, MARCKSL1P2, HEBP2, NHSL1, MIR3145, AL391669.1, AL590617.1, AL590617.2, CCDC28A-AS1, CCDC28A.
- chr12:5,226,196–34,058,745, 700 genes, copy number 8–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 119. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
